Gene-level copy-number profile of tumor specimen TCGA-44-7660-01A from TCGA case TCGA-44-7660, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.8 years (26,594 days).
Specimen TCGA-44-7660-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.c587d2b5-71e6-4900-b596-79c928f365f4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-7660-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3270417d-004a-4046-91aa-5e66a5cc21f6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 24,358; copy number 2: 30,774; copy number 3: 2,928; copy number 4: 1,260; copy number 5: 125; copy number 7: 367.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-7660-01A-11D-2062-01): tumor purity 0.58, ploidy 3.25, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 492 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:34,640,157–41,484,683, 217 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:41,535,443–41,628,816, 3 genes, copy number 7 (within-gene range 4–7): AL445933.2, AL445933.1, AC119676.1.
- chr1:43,946,950–47,408,477, 131 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:50,780,340–54,639,192, 134 genes, copy number 7 (broad region; genes not listed).
- chr1:73,635,216–73,715,214, 1 gene, copy number 5 (within-gene range 2–5): LINC02238.
- chr1:82,970,820–82,986,208, 1 gene, copy number 5: LINC01361.
- chr3:189,238,686–189,240,594, 1 gene, copy number 7: TPRG1-AS2.
- chr3:190,680,421–190,892,429, 4 genes, copy number 5: LINC02013, CCT6P4, AC092952.1, GMNC.

Autosomal genes at a single copy (total copy number 1): 21,937. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
